Somatic mutation profile of tumor specimen TCGA-LB-A7SX-01A (aliquot TCGA-LB-A7SX-01A-11D-A33T-08) from TCGA case TCGA-LB-A7SX, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 74.7 years (27,295 days).
Specimen TCGA-LB-A7SX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92e7cb9f-fc8c-4c7a-ae69-53ed1f6378b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LB-A7SX-10A (Blood Derived Normal), aliquot TCGA-LB-A7SX-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/099f663e-2ca2-4ef3-8ac6-9a490fdee4b9

The open-access MAF lists 112 somatic variants for this specimen: 77 protein-altering or splice-affecting, 30 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 30, Nonsense Mutation 7, Intron 3, Frame Shift Del 2, Splice Site 1, Splice Region 1, Frame Shift Ins 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 109/232 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 93/193 reads (48%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.700C>A p.H234N | Missense Mutation (SNP) | VAF 167/492 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV99941584; called by muse, mutect2, varscan2
- ADGRE5 | c.1474G>A p.E492K (on ENST00000242786 / NM_078481.4; = p.E399K on NM_001784.5) | Missense Mutation (SNP) | VAF 227/689 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.122); catalogued as COSV99660337; called by muse, mutect2, varscan2
- AFF3 | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100419219, COSV57850902; called by muse, mutect2
- AOC2 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 152/498 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99513661; called by muse, mutect2, varscan2
- ARHGAP32 | c.2780C>T p.S927L (on ENST00000310343 / NM_001378025.1; = p.S578L on NM_014715.4) | Missense Mutation (SNP) | VAF 96/449 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100088069; called by muse, mutect2, varscan2
- ARMC9 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761665532, COSV63019497; called by muse, mutect2, varscan2
- ASRGL1 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 81/439 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100077944, COSV57123576; called by muse, mutect2, varscan2
- ATP12A | c.1603A>G p.T535A | Missense Mutation (SNP) | VAF 33/562 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99517817; called by muse, mutect2
- C10orf71 | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 80/333 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100110275; called by muse, mutect2, varscan2
- CASP2 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 98/352 reads (28%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.904); catalogued as COSV100131041; called by muse, mutect2, varscan2
- CBLL2 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 27/698 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1257570318, COSV60368932; called by muse, mutect2
- CDH22 | c.1333G>C p.D445H | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV100952894; called by muse, mutect2
- CLK2 | c.1297G>C p.E433Q (on ENST00000368361 / NM_001294339.2; = p.E432Q on NM_003993.4) | Missense Mutation (SNP) | VAF 155/824 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs751530422, COSV100226775; called by muse, mutect2, varscan2
- CNTNAP4 | c.3094C>T p.H1032Y | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV56663738, COSV56690517; called by muse, mutect2, varscan2
- COL24A1 | c.3404C>A p.P1135H | Missense Mutation (SNP) | VAF 218/634 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.279); catalogued as COSV100993479, COSV65306470; called by muse, mutect2, varscan2
- CYP2R1 | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100584932; called by muse, mutect2, varscan2
- DACH1 | c.2216C>T p.T739I (on ENST00000619232 / NM_001366712.1; = p.T485I on NM_004392.6) | Missense Mutation (SNP) | VAF 91/363 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.115); catalogued as COSV100498556; called by muse, mutect2, varscan2
- DBT | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 85/463 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100923527; called by muse, mutect2, varscan2
- DMBT1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 44/1304 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV57543746; called by muse, mutect2
- ECT2 | c.961C>A p.L321I (on ENST00000392692 / NM_001349098.2; = p.L290I on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/349 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99221444; called by muse, mutect2, varscan2
- EFCAB1 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs766485323, COSV100030834, COSV50620520; called by muse, mutect2
- EIF2AK2 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs747731290, COSV99240738; called by muse, mutect2
- EIF3D | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 170/609 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs867464440, COSV99341598; called by muse, mutect2, varscan2
- FAM184A | c.3077C>T p.T1026I | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58855210; called by muse, mutect2
- FBXO43 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 161/640 reads (25%) | catalogued as COSV71054504; called by muse, mutect2, varscan2
- GDI2 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 98/497 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV100050586; called by muse, mutect2, varscan2
- GLI3 | c.1562C>A p.S521* | Nonsense Mutation (SNP) | VAF 159/449 reads (35%) | catalogued as COSV101229910; called by muse, mutect2, varscan2
- GRM1 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51310207, COSV99266741; called by muse, mutect2, varscan2
- HADH | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 296/806 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV100531222; called by muse, mutect2, varscan2
- HCAR1 | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 25/492 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV100811644; called by muse, mutect2
- HDAC9 | c.2012C>A p.T671N | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as COSV101286815, COSV67776950; called by muse, mutect2, varscan2
- HTR5A | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1204412791, COSV55280731; called by muse, mutect2
- IFIH1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 99/364 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV55124642, COSV99718675; called by muse, mutect2, varscan2
- INPP4A | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.559); catalogued as rs1320693278, COSV50785335; called by muse, mutect2
- KLHL1 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 61/187 reads (33%) | catalogued as COSV100917477; called by muse, mutect2, varscan2
- LOXL1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs141057976; called by muse, mutect2, varscan2
- LRCH1 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 81/346 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs753917959, COSV60846100; called by muse, mutect2, varscan2
- MACROH2A2 | c.717A>C p.K239N | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100951955; called by muse, mutect2, varscan2
- MAP11 | c.508A>T p.I170F | Missense Mutation (SNP) | VAF 178/781 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV100385533; called by muse, mutect2, varscan2
- MUC16 | c.23140C>T p.P7714S | Missense Mutation (SNP) | VAF 51/340 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.084); catalogued as COSV101200175; called by muse, mutect2, varscan2
- NCKAP5 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV100492602; called by muse, mutect2, varscan2
- NGDN | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 18/250 reads (7%) | catalogued as rs956675034, COSV68142582; called by muse, mutect2
- OR51B2 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 49/376 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60916252, COSV60918089; called by muse, mutect2, varscan2
- OR52N5 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs144845456, COSV57699390; called by muse, mutect2, varscan2
- PCDH15 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV100222154; called by muse, mutect2, varscan2
- PCDH9 | c.2961T>G p.S987R | Missense Mutation (SNP) | VAF 139/452 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV100121397; called by muse, mutect2, varscan2
- PIEZO2 | c.6975G>C p.K2325N | Missense Mutation (SNP) | VAF 175/601 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99555101; called by muse, mutect2, varscan2
- PIGQ | c.1676C>A p.A559E (on ENST00000026218 / NM_148920.3; = p.Q580K on NM_004204.5) | Missense Mutation (SNP) | VAF 31/616 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV99216180; called by muse, mutect2
- PREX1 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 463/1470 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV100906459; called by muse, mutect2, varscan2
- PRKDC | c.11690T>G p.F3897C | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100041059; called by muse, mutect2, varscan2
- PRL | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 175/361 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as rs139327343; called by muse, mutect2, varscan2
- PRPF6 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 86/259 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99412155; called by muse, mutect2, varscan2
- PSG7 | c.738C>G p.I246M | Missense Mutation (SNP) | VAF 62/1664 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.888); catalogued as COSV101343268; called by muse, mutect2
- RANBP2 | c.1332G>A p.W444* | Nonsense Mutation (SNP) | VAF 237/1018 reads (23%) | catalogued as COSV99312343; called by muse, mutect2, varscan2
- RHCE | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 64/678 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs1333227775, COSV99604119; called by muse, mutect2
- RINT1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 40/464 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866948739, COSV57559240; ClinVar: uncertain significance; called by muse, mutect2
- SCAP | c.3793G>A p.E1265K | Missense Mutation (SNP) | VAF 46/1048 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV99650697; called by muse, mutect2
- SH2B1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 183/745 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.546); catalogued as rs1460739551, COSV100451098; called by muse, mutect2, varscan2
- SH3BP4 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 48/416 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV100749207; called by muse, mutect2, varscan2
- SMYD5 | c.924T>G p.F308L | Missense Mutation (SNP) | VAF 89/779 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99240274; called by muse, mutect2, varscan2
- SRSF4 | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 294/940 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV100861412; called by muse, mutect2, varscan2
- STAC3 | c.336C>T p.L112= | Splice Region (SNP) | VAF 447/911 reads (49%) | catalogued as COSV100234623; called by muse, mutect2, varscan2
- STK10 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 22/485 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99451722; called by muse, mutect2
- SUGT1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 61/255 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.131); catalogued as rs769835124, COSV100139545; called by muse, mutect2, varscan2
- WIF1 | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV54129763, COSV99682998; called by muse, mutect2, varscan2
- XPR1 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 101/420 reads (24%) | catalogued as COSV100851482; called by muse, mutect2, varscan2
- XRN1 | c.628-1G>A p.X210_splice | Splice Site (SNP) | VAF 56/282 reads (20%) | catalogued as COSV99378202; called by muse, varscan2
- XYLT1 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 154/642 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV54477949, COSV99762091; called by muse, mutect2, varscan2
- ZNF521 | c.3178C>A p.H1060N | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV100832478; called by muse, mutect2
- COG3 | c.549+1dup | Frame Shift Ins (INS) | VAF 73/298 reads (24%) | called by mutect2, pindel, varscan2
- COL3A1 | c.2653G>A p.G885S | Missense Mutation (SNP) | VAF 20/459 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- FBXW7 | c.872_873del p.Y291Cfs*25 (on ENST00000281708 / NM_001349798.2; = p.Y211Cfs*25 on NM_018315.5) | Frame Shift Del (DEL) | VAF 61/207 reads (29%) | called by mutect2, pindel, varscan2
- GNB1 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2
- KMT2C | c.9868del p.L3290* | Frame Shift Del (DEL) | VAF 83/441 reads (19%) | called by mutect2, pindel, varscan2
- OR8B12 | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 19/565 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2
- ADCY5 | c.3222C>T p.F1074= | Silent (SNP) | VAF 86/448 reads (19%) | catalogued as rs961682801, COSV59197619, COSV59205137; called by muse, mutect2, varscan2
- B3GALT5 | c.162G>A p.Q54= | Silent (SNP) | VAF 90/431 reads (21%) | catalogued as COSV100563396; called by muse, mutect2, varscan2
- CADM4 | c.841C>T p.L281= | Silent (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
- CERK | c.1212C>A p.P404= | Silent (SNP) | VAF 78/420 reads (19%) | catalogued as rs201852137, COSV99348643; called by muse, mutect2, varscan2
- EEF2KMT | c.255C>T p.H85= | Silent (SNP) | VAF 103/391 reads (26%) | catalogued as COSV101435301; called by muse, mutect2, varscan2
- FBXO45 | c.573T>C p.S191= | Silent (SNP) | VAF 56/178 reads (31%) | catalogued as COSV100291014; called by muse, mutect2, varscan2
- GPR156 | c.184C>T p.L62= | Silent (SNP) | VAF 184/540 reads (34%) | catalogued as rs1403015597, COSV100251430; called by muse, varscan2
- JAKMIP1 | c.576C>T p.D192= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as rs752560124, COSV99289838; called by muse, varscan2
- KIF5B | c.2148C>T p.I716= | Silent (SNP) | VAF 19/602 reads (3%) | called by muse, mutect2
- MCM3AP | c.2802G>A p.L934= | Silent (SNP) | VAF 38/1355 reads (3%) | catalogued as COSV99387082; called by muse, mutect2
- MED1 | c.1437C>T p.L479= | Silent (SNP) | VAF 48/1500 reads (3%) | catalogued as COSV100327884, COSV56124161; called by muse, mutect2
- MEGF11 | c.2016C>T p.N672= | Silent (SNP) | VAF 48/260 reads (18%) | catalogued as rs767950937, COSV99987114; called by muse, mutect2, varscan2
- NDC1 | c.1056C>T p.L352= | Silent (SNP) | VAF 320/1148 reads (28%) | catalogued as rs902264815, COSV99323686, COSV99323888; called by muse, mutect2, varscan2
- NID2 | c.1860C>T p.F620= | Silent (SNP) | VAF 149/429 reads (35%) | catalogued as rs771716532, COSV99356701; called by muse, mutect2, varscan2
- OR4Q3 | c.288G>A p.Q96= | Silent (SNP) | VAF 161/728 reads (22%) | catalogued as COSV100057118; called by muse, mutect2, varscan2
- OR6X1 | c.12C>T p.G4= | Silent (SNP) | VAF 143/671 reads (21%) | catalogued as COSV100020563; called by muse, mutect2, varscan2
- OTUD4 | c.909A>T p.A303= (on ENST00000447906 / NM_001366057.1; = p.A238= on NM_001102653.1) | Silent (SNP) | VAF 53/261 reads (20%) | catalogued as COSV101485997; called by muse, mutect2, varscan2
- OTUD7B | c.1917C>T p.F639= | Silent (SNP) | VAF 168/847 reads (20%) | catalogued as COSV100967602; called by muse, mutect2, varscan2
- PAPSS1 | c.15G>A p.G5= | Silent (SNP) | VAF 125/497 reads (25%) | catalogued as COSV54488329; called by muse, mutect2, varscan2
- POPDC3 | c.348C>T p.F116= | Silent (SNP) | VAF 331/708 reads (47%) | catalogued as COSV99633811; called by muse, mutect2, varscan2
- R3HCC1L | c.2331C>T p.A777= (on ENST00000612478 / NM_001256619.2; = p.A763= on NM_014472.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 60/333 reads (18%) | catalogued as COSV99583959; called by muse, mutect2, varscan2
- RNF26 | c.1155C>T p.D385= | Silent (SNP) | VAF 16/454 reads (4%) | called by muse, mutect2
- RTL9 | c.3468A>G p.E1156= | Silent (SNP) | VAF 48/441 reads (11%) | catalogued as COSV101511711; called by muse, mutect2, varscan2
- SHROOM4 | c.1914T>C p.S638= | Silent (SNP) | VAF 47/441 reads (11%) | catalogued as COSV99173640; called by muse, mutect2, varscan2
- SLC7A10 | c.1494C>T p.D498= | Silent (SNP) | VAF 70/240 reads (29%) | catalogued as rs758217073, COSV99472311; called by muse, mutect2, varscan2
- TACR3 | c.312C>G p.L104= | Silent (SNP) | VAF 27/473 reads (6%) | catalogued as COSV100510418; called by muse, mutect2
- TMPRSS15 | c.2469C>T p.A823= | Silent (SNP) | VAF 52/316 reads (16%) | catalogued as rs763270693, COSV53048778; called by muse, mutect2, varscan2
- TRAF3 | c.1706G>A p.*569= | Silent (SNP) | VAF 46/145 reads (32%) | catalogued as COSV100693632; called by muse, mutect2, varscan2
- VIRMA | c.1815G>A p.V605= | Silent (SNP) | VAF 39/780 reads (5%) | catalogued as rs1217337372, COSV99888602; called by muse, mutect2
- ZNF217 | c.2382G>A p.Q794= | Silent (SNP) | VAF 145/477 reads (30%) | catalogued as COSV100184894, COSV56603355; called by muse, mutect2, varscan2
- CDC42 | c.487-1441C>T | Intron (SNP) | VAF 41/298 reads (14%) | catalogued as COSV100212610; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85552G>A | Intron (SNP) | VAF 30/243 reads (12%) | catalogued as COSV72278952; called by muse, mutect2, varscan2
- NTRK3 | c.1586-40498G>T | Intron (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100446839; called by muse, mutect2, varscan2
- NXT2 | c.-69C>T | 5'UTR (SNP) | VAF 20/161 reads (12%) | catalogued as COSV99484034; called by muse, mutect2, varscan2
- SNORD115-17 | n.44G>A | RNA (SNP) | VAF 50/1292 reads (4%) | called by muse, mutect2
